Somatic mutation profile of tumor specimen 0D9W5F from CCDI case PBBJGW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.3 years (1,933 days).
Specimen 0D9W5F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 612ce63b-6c9b-496e-b5ca-7ffddcea71b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0D9W5G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5673010-92a0-490f-9c6f-96ed37400a2d

The open-access MAF lists 11 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, 3'UTR 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXN4 | c.820C>T p.R274C | Missense Mutation (SNP) | VAF 65/411 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs753454851; called by muse, varscan2
- MYOM1 | c.3182C>T p.P1061L | Missense Mutation (SNP) | VAF 42/402 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as rs1028776972; called by mutect2, varscan2
- NPAP1 | c.3256G>A p.A1086T | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs201894790, COSV61505775; called by muse, mutect2, varscan2
- P3H3 | c.1993C>T p.R665W | Missense Mutation (SNP) | VAF 32/590 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs368711010; called by muse, mutect2
- RAPGEF2 | c.147T>A p.S49R | Missense Mutation (SNP) | VAF 14/434 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ARHGEF10 | c.3981G>A p.K1327= (on ENST00000398564; = p.K1302= on NM_014629.4) | Silent (SNP) | VAF 17/308 reads (6%) | called by muse, mutect2
- KRT7 | c.1194C>T p.G398= | Silent (SNP) | VAF 48/632 reads (8%) | catalogued as rs764325393; called by muse, mutect2
- PSMB3 | c.504C>T p.S168= | Silent (SNP) | VAF 85/505 reads (17%) | called by muse, mutect2, varscan2
- C1S | c.5+99C>T | Intron (SNP) | VAF 6/54 reads (11%) | catalogued as rs1026641562; called by muse, mutect2
- CRIPT | c.*53T>A | 3'UTR (SNP) | VAF 16/158 reads (10%) | called by muse, varscan2
- CSF2RA | c.*36G>A | 3'UTR (SNP) | VAF 71/496 reads (14%) | catalogued as rs144367097, COSV62625342; called by muse, mutect2, varscan2
